Somatic mutation profile of tumor specimen C3L-05518-01 (aliquot CPT0335020006) from CPTAC case C3L-05518, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 80.0 years (29,238 days).
Specimen C3L-05518-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0e09198-2979-47b5-b921-549710c63c24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05518-31 (Blood Derived Normal), aliquot CPT0335000002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4391b873-78e5-4280-9066-9e52da3523bc

The open-access MAF lists 38 somatic variants for this specimen: 29 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 8, 3'UTR 1, Translation Start Site 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 143/353 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BIN1 | c.916G>A p.A306T (on ENST00000316724 / NM_001320642.1; = p.A290T on NM_004305.4) | Missense Mutation (SNP) | VAF 213/633 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs746786096; called by muse, mutect2, varscan2
- CD209 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 79/254 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs370333676, COSV99213534; called by muse, mutect2, varscan2
- DNAH5 | c.11722A>C p.N3908H | Missense Mutation (SNP) | VAF 125/334 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV54222131; called by muse, mutect2, varscan2
- DNAH5 | c.11585C>T p.P3862L | Missense Mutation (SNP) | VAF 106/297 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs763954304; called by muse, mutect2, varscan2
- DYRK1B | c.1141G>A p.V381M | Missense Mutation (SNP) | VAF 167/528 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs763854386; called by muse, mutect2, varscan2
- HEATR1 | c.125A>G p.D42G | Missense Mutation (SNP) | VAF 118/320 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV63979379; called by muse, varscan2
- KIAA1958 | c.1375G>T p.E459* | Nonsense Mutation (SNP) | VAF 40/184 reads (22%) | catalogued as rs767238067; called by muse, mutect2, varscan2
- NLRP13 | c.2648C>T p.A883V | Missense Mutation (SNP) | VAF 141/395 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV61623747; called by muse, mutect2, varscan2
- PRB3 | c.277C>A p.P93T | Missense Mutation (SNP) | VAF 206/404 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as COSV54388048; called by mutect2, varscan2
- SPHKAP | c.3664G>A p.G1222S | Missense Mutation (SNP) | VAF 157/429 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs539804675; called by muse, mutect2, varscan2
- AL662899.2 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 152/543 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BAZ2B | c.1537A>G p.T513A | Missense Mutation (SNP) | VAF 87/409 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CEP295 | c.1369G>A p.G457R | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH6 | c.2320G>T p.A774S | Missense Mutation (SNP) | VAF 67/1293 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.358); called by muse, mutect2
- EFR3B | c.2125A>T p.S709C | Missense Mutation (SNP) | VAF 136/562 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- FGFRL1 | c.1466A>T p.H489L | Missense Mutation (SNP) | VAF 220/601 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- FMN1 | c.1548_1549del p.Q516Hfs*30 | Frame Shift Del (DEL) | VAF 91/534 reads (17%) | called by mutect2, pindel, varscan2
- KRT31 | c.833C>T p.T278I | Missense Mutation (SNP) | VAF 71/627 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- LOXL2 | c.1842G>C p.K614N | Missense Mutation (SNP) | VAF 217/664 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MAGI1 | c.394A>G p.T132A | Missense Mutation (SNP) | VAF 24/736 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.085); called by muse, mutect2
- NRXN1 | c.2681A>T p.N894I | Missense Mutation (SNP) | VAF 53/384 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SOX6 | c.388G>T p.V130L | Missense Mutation (SNP) | VAF 151/341 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TCTN3 | c.1235G>C p.S412T | Missense Mutation (SNP) | VAF 95/217 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOPAZ1 | c.1502G>A p.R501K | Missense Mutation (SNP) | VAF 57/364 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF425 | c.2116A>G p.K706E | Missense Mutation (SNP) | VAF 80/567 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- ZNF425 | c.1766A>G p.K589R | Missense Mutation (SNP) | VAF 68/528 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF425 | c.1655A>G p.E552G | Missense Mutation (SNP) | VAF 87/646 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ZNF425 | c.833A>G p.E278G | Missense Mutation (SNP) | VAF 39/762 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.398); called by muse, mutect2
- AMIGO1 | c.1374G>A p.K458= | Silent (SNP) | VAF 79/499 reads (16%) | called by muse, mutect2, varscan2
- CAMTA1 | c.1092C>T p.S364= | Silent (SNP) | VAF 93/315 reads (30%) | catalogued as rs370847468; called by muse, mutect2, varscan2
- FRMPD4 | c.2931C>A p.T977= | Silent (SNP) | VAF 81/436 reads (19%) | catalogued as rs759789728; called by muse, mutect2, varscan2
- MYO18B | c.6223C>A p.R2075= | Silent (SNP) | VAF 154/469 reads (33%) | called by muse, mutect2, varscan2
- MYO6 | c.3099G>A p.A1033= | Silent (SNP) | VAF 58/255 reads (23%) | catalogued as COSV100889388; called by muse, mutect2, varscan2
- NBAS | c.1530A>G p.R510= | Silent (SNP) | VAF 72/415 reads (17%) | called by muse, mutect2, varscan2
- TMEM17 | c.415T>C p.L139= | Silent (SNP) | VAF 227/506 reads (45%) | called by muse, mutect2, varscan2
- ZNF536 | c.579C>T p.R193= | Silent (SNP) | VAF 109/689 reads (16%) | catalogued as COSV62821165, COSV62836290; called by muse, mutect2, varscan2
- RIMS3 | c.*1G>T | 3'UTR (SNP) | VAF 15/346 reads (4%) | catalogued as rs1335663437; called by muse, mutect2
